Gene-level copy-number profile of tumor specimen TCGA-24-1470-01A from TCGA case TCGA-24-1470, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 54.8 years (20,007 days).
Specimen TCGA-24-1470-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.f5e1743a-9f6f-4dd5-9ff4-d87e87417699.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1470-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ab4f25bc-ee99-4c2d-b69c-f82239c2cf67

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 16,055; copy number 2: 36,216; copy number 3: 6,605; copy number 4: 736; copy number 5: 194.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1470-01A-01D-0497-01): tumor purity 0.84, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:65,009,289–66,256,525, 12 genes (within-gene range 0–1): GNA13, AC037487.2, RGS9, AC060771.1, LINC02563, AXIN2, AC004805.1, CEP112, AC004805.3, AC004805.2, PSMD7P1, APOH.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 194 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:172,609,094–172,785,424, 11 genes, copy number 5: AC027309.3, NEURL1B, AC027309.2, MIR5003, AC027309.1, AC022217.2, AC022217.1, AC022217.3, DUSP1, Y_RNA, AC022217.4.
- chr7:139,561,570–140,176,983, 5 genes, copy number 5 (within-gene range 3–5): HIPK2, TBXAS1, PARP12, KDM7A, Y_RNA.
- chr8:117,520,713–129,683,770, 178 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,690. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
